Somatic mutation profile of cancer-model specimen HCM-BROD-0450-C15-85M (3D Organoid, passage 5; aliquot HCM-BROD-0450-C15-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0450-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 52.4 years (19,140 days).
Specimen HCM-BROD-0450-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 356f4d9c-6cb9-4500-8d77-a97c2467a2d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0450-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0450-C15-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30f7cbaa-c692-419c-a6f6-5c2edb128900

The open-access MAF lists 137 somatic variants for this specimen: 97 protein-altering or splice-affecting, 33 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 33, Intron 5, Frame Shift Del 5, Nonsense Mutation 4, 5'Flank 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL3 | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 389/390 reads (100%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV100206820; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 131/241 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs945253912; called by muse, mutect2, varscan2
- AJAP1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 351/351 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373393328; called by muse, mutect2, varscan2
- ARHGEF28 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs754962592, COSV55256803; called by muse, mutect2, varscan2
- CCDC166 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 225/474 reads (47%) | catalogued as rs782021652; called by muse, mutect2, varscan2
- CCDC181 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 166/348 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63157671; called by muse, mutect2, varscan2
- CCT8 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 202/325 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54503949; called by muse, mutect2, varscan2
- CDH6 | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 121/312 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV54069412, COSV99420061; called by muse, mutect2, varscan2
- COL22A1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 328/328 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV57324808; called by muse, mutect2, varscan2
- CSNK1A1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1326635408, COSV99939796; called by muse, mutect2, varscan2
- CXCR4 | c.931A>T p.T311S | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV54011334; called by muse, mutect2
- DENND5B | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs201039344; called by muse, mutect2, varscan2
- HMCN1 | c.7946C>T p.T2649M | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150251628; called by muse, mutect2, varscan2
- IFI44L | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100655097; called by muse, mutect2, varscan2
- ITGA7 | c.3371C>T p.A1124V (on ENST00000555728; = p.A1080V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/436 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs201977360, COSV57692534; called by muse, mutect2, varscan2
- KCNT2 | c.2244A>C p.E748D | Missense Mutation (SNP) | VAF 101/189 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV54088716; called by muse, mutect2, varscan2
- NCR3 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 257/1820 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs557571503; called by muse, mutect2, varscan2
- ORM1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 155/498 reads (31%) | catalogued as rs776100400, COSV99035321; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PEAR1 | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 217/447 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs149758169; called by muse, mutect2, varscan2
- PGAP1 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.755); catalogued as COSV61330375; called by muse, mutect2
- PNISR | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 114/211 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747118741; called by muse, mutect2, varscan2
- SCGB1C1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 44/729 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770850758, COSV100285330, COSV57292571; called by muse, mutect2
- SCN2A | c.2419T>C p.F807L | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1419924604; called by muse, mutect2, varscan2
- SLC35E1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 140/269 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs749199081; called by muse, mutect2, varscan2
- SPOCK3 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 116/211 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.106); catalogued as COSV62717823; called by muse, mutect2, varscan2
- TACC2 | c.5404G>A p.E1802K | Missense Mutation (SNP) | VAF 155/369 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs199828025; called by muse, mutect2
- TRPM6 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772202783, COSV62512597; called by muse, mutect2, varscan2
- VARS1 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 211/1528 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs527997607; called by muse, mutect2, varscan2
- VPS72 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 217/361 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs750661899; called by muse, mutect2, varscan2
- ZFP28 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.418); catalogued as COSV56737936; called by muse, mutect2, varscan2
- ZNF721 | c.2562_2563del p.C855Wfs*8 (on ENST00000338977; = p.C867Wfs*8 on NM_133474.4) | Frame Shift Del (DEL) | VAF 266/372 reads (72%) | catalogued as rs781904937; called by mutect2, pindel, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 190/735 reads (26%) | catalogued as rs750329558; called by mutect2, varscan2
- ACAD8 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); called by muse, mutect2
- ADGRD1 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD36C | c.1121_1127del p.E374Vfs*2 | Frame Shift Del (DEL) | VAF 38/40 reads (95%) | called by mutect2, pindel, varscan2
- AOC1 | c.2101T>C p.F701L | Missense Mutation (SNP) | VAF 433/434 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ATP2B2 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 194/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCAN | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 48/670 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BOD1L1 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 83/167 reads (50%) | called by muse, mutect2, varscan2
- BRINP1 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C7orf25 | c.138A>T p.L46F | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CADPS | c.2217A>C p.E739D | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC14B | c.790A>T p.N264Y | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAC1 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 492/492 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CHL1 | c.126A>C p.K42N | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- CHST6 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 231/714 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CSE1L | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2
- CUBN | c.9539A>T p.D3180V | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- CUX2 | c.2886G>C p.Q962H | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CYP2C9 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 137/260 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- DDX39A | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 150/439 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DISP3 | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 52/606 reads (9%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- DPH2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DYNC2H1 | c.10942T>C p.W3648R | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYRK3 | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EI24 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENO4 | c.1407T>G p.I469M (on ENST00000622726; = p.I466M on NM_001242699.2) | Missense Mutation (SNP) | VAF 134/266 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- EPHA1 | c.1337-7C>A | Splice Region (SNP) | VAF 327/328 reads (100%) | called by muse, mutect2, varscan2
- FAT1 | c.2971T>C p.F991L | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2
- FAT4 | c.2525A>C p.N842T | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2
- GABRB1 | c.803A>C p.N268T | Missense Mutation (SNP) | VAF 251/251 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GUF1 | c.1721A>T p.K574I | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- HSD3B2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 187/602 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ISLR2 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2
- KIF14 | c.983G>T p.R328I | Missense Mutation (SNP) | VAF 161/320 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL22 | c.1600C>G p.H534D | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- MAML1 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 398/398 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.6656_6657delinsT p.K2219Ifs*32 (on ENST00000397909 / NM_001024383.2; = p.K2197Ifs*32 on NM_014903.6) | Frame Shift Del (DEL) | VAF 83/384 reads (22%) | called by pindel, varscan2*
- NES | c.2047G>T p.V683L | Missense Mutation (SNP) | VAF 24/423 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- NFAT5 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NKX2-6 | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 227/479 reads (47%) | called by muse, mutect2, varscan2
- NMT1 | c.155C>G p.T52S | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2
- NPAP1 | c.1477C>T p.L493F | Missense Mutation (SNP) | VAF 183/371 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPEPL1 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 31/876 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2
- OFD1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OR6P1 | c.554T>A p.L185H | Missense Mutation (SNP) | VAF 135/284 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPOLA | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2
- PDE6C | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLA2G4E | c.273T>G p.C91W | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POTEB2 | c.759T>G p.F253L | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- PPP1R15B | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 76/720 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R26 | c.2507G>A p.S836N | Missense Mutation (SNP) | VAF 139/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO2 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A1 | c.2612A>T p.K871M | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SLC9A4 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 245/246 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SMPD4 | c.2120T>G p.L707R (on ENST00000409031 / NM_017951.4; = p.L678R on NM_017751.4) | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SPATA31A3 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by mutect2, varscan2
- STEAP1 | c.318T>A p.F106L | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TPO | c.1964G>A p.C655Y | Missense Mutation (SNP) | VAF 639/639 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM22 | c.437dup p.A147Sfs*13 | Frame Shift Ins (INS) | VAF 98/277 reads (35%) | called by mutect2, pindel, varscan2
- TRIM64B | c.520A>G p.R174G | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TTN | c.42658A>C p.S14220R (on ENST00000591111; = p.S6796R on NM_003319.4) | Missense Mutation (SNP) | VAF 46/205 reads (22%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UQCRB | c.211T>G p.L71V | Missense Mutation (SNP) | VAF 89/433 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UQCRQ | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USH2A | c.13910del p.P4637Lfs*41 | Frame Shift Del (DEL) | VAF 183/424 reads (43%) | called by mutect2, pindel, varscan2
- USHBP1 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AK6 | c.9T>C p.L3= | Silent (SNP) | VAF 222/224 reads (99%) | called by muse, mutect2, varscan2
- BRAT1 | c.228A>G p.S76= | Silent (SNP) | VAF 301/303 reads (99%) | called by muse, mutect2, varscan2
- C4A | c.3339T>C p.A1113= | Silent (SNP) | VAF 160/445 reads (36%) | catalogued as rs1471080180; called by muse, mutect2, varscan2
- CADPS | c.3255A>G p.E1085= | Silent (SNP) | VAF 290/290 reads (100%) | called by muse, mutect2, varscan2
- CCNF | c.1533C>T p.T511= | Silent (SNP) | VAF 152/318 reads (48%) | catalogued as rs374851448; called by muse, mutect2, varscan2
- CR2 | c.828C>T p.C276= | Silent (SNP) | VAF 74/168 reads (44%) | called by muse, mutect2, varscan2
- DLGAP1 | c.288G>A p.A96= | Silent (SNP) | VAF 245/470 reads (52%) | catalogued as rs1383959419; called by muse, mutect2, varscan2
- ERBB4 | c.3118A>C p.R1040= | Silent (SNP) | VAF 73/229 reads (32%) | catalogued as rs1312805783, COSV61484722; called by muse, mutect2, varscan2
- FAM135A | c.2707T>C p.L903= (on ENST00000370479 / NM_001351599.1; = p.L690= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- GABRG2 | c.180A>G p.K60= | Silent (SNP) | VAF 147/253 reads (58%) | catalogued as COSV62715881; called by muse, mutect2, varscan2
- HERC2 | c.261T>G p.T87= | Silent (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- KCNT1 | c.1407C>T p.Y469= (on ENST00000488444; = p.Y488= on NM_020822.3) | Silent (SNP) | VAF 190/324 reads (59%) | catalogued as rs375585422; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAPRT | c.1062C>G p.V354= | Silent (SNP) | VAF 206/421 reads (49%) | catalogued as COSV99434829; called by muse, mutect2, varscan2
- NCDN | c.324G>A p.V108= | Silent (SNP) | VAF 472/472 reads (100%) | called by muse, mutect2, varscan2
- OAS2 | c.1293C>T p.I431= | Silent (SNP) | VAF 261/261 reads (100%) | catalogued as rs186647423, COSV60801480; called by muse, mutect2, varscan2
- OR8J1 | c.483T>G p.S161= | Silent (SNP) | VAF 127/259 reads (49%) | catalogued as COSV57317495; called by muse, mutect2, varscan2
- PHLDB1 | c.1041T>C p.T347= | Silent (SNP) | VAF 15/533 reads (3%) | called by muse, mutect2
- PORCN | c.795G>A p.T265= (on ENST00000326194 / NM_203475.3; = p.T254= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as rs781949383, COSV58226048; called by muse, mutect2, varscan2
- PPRC1 | c.4221A>G p.K1407= | Silent (SNP) | VAF 222/438 reads (51%) | called by muse, mutect2, varscan2
- PTPRB | c.3675G>C p.T1225= | Silent (SNP) | VAF 91/293 reads (31%) | catalogued as COSV54238505, COSV99717076; called by muse, mutect2, varscan2
- RUSF1 | c.1218C>T p.N406= | Silent (SNP) | VAF 144/308 reads (47%) | catalogued as rs137933115; called by muse, mutect2, varscan2
- SLITRK1 | c.669G>T p.L223= | Silent (SNP) | VAF 133/473 reads (28%) | called by muse, mutect2, varscan2
- SPIRE2 | c.234C>G p.P78= | Silent (SNP) | VAF 98/336 reads (29%) | called by muse, mutect2, varscan2
- SPOCD1 | c.471G>A p.E157= | Silent (SNP) | VAF 200/364 reads (55%) | called by muse, mutect2, varscan2
- SRPK1 | c.1278G>A p.V426= | Silent (SNP) | VAF 72/351 reads (21%) | catalogued as rs747832186; called by muse, mutect2, varscan2
- TBRG1 | c.813G>T p.L271= | Silent (SNP) | VAF 91/151 reads (60%) | called by muse, mutect2, varscan2
- TTN | c.84618T>G p.T28206= (on ENST00000591111; = p.T20782= on NM_003319.4) | Silent (SNP) | VAF 374/374 reads (100%) | called by muse, mutect2, varscan2
- UBR3 | c.3765A>G p.V1255= | Silent (SNP) | VAF 207/310 reads (67%) | catalogued as rs956328062; called by muse, mutect2, varscan2
- UNC45B | c.2091T>A p.A697= | Silent (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2
- ZFHX3 | c.2763G>A p.Q921= | Silent (SNP) | VAF 101/491 reads (21%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2721C>A p.V907= | Silent (SNP) | VAF 123/424 reads (29%) | catalogued as COSV101023689; called by muse, mutect2, varscan2
- ZNF165 | c.276G>A p.L92= | Silent (SNP) | VAF 130/322 reads (40%) | catalogued as COSV101055840; called by muse, mutect2, varscan2
- ZNF699 | c.1581A>C p.G527= | Silent (SNP) | VAF 12/378 reads (3%) | called by muse, mutect2
- BCAT1 | c.7-1088C>T | Intron (SNP) | VAF 117/396 reads (30%) | catalogued as COSV53913908; called by muse, mutect2, varscan2
- CCDC40 | c.1562+2004C>T | Intron (SNP) | VAF 293/294 reads (100%) | catalogued as rs902840891; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-2005G>T | Intron (SNP) | VAF 102/224 reads (46%) | called by muse, mutect2, varscan2
- MAGI3 | c.3329-683T>A | Intron (SNP) | VAF 93/341 reads (27%) | called by muse, mutect2, varscan2
- OSGIN1 | n.418G>A | RNA (SNP) | VAF 114/394 reads (29%) | catalogued as rs748284485; called by muse, mutect2, varscan2
- PITX2 | c.390+262G>C | Intron (SNP) | VAF 130/345 reads (38%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532482 T>G | 5'Flank (SNP) | VAF 124/266 reads (47%) | called by muse, mutect2
